Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A706, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A706-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Inferior margin, 1FS: Fibroadipose tissue, no tumor seen.
2. Inferior margin #2, 2FS: Lymph node, no tumor seen.
3. Lateral margin, 3FS: Fibroadipose tissue, no tumor seen.
4. Medial margin, 4FS: Fibroadipose tissue, no tumor seen.
5. Soft tissue, right thoracic, paraganglioma, resection:
Extra-adrenal pheochromocytoma (paraganglioma); Two lymph nodes,
no tumor seen; Margins of resection are free of tumor (see note).

NOTE: Immunohistochemical studies demonstrate tumor cells staining positively for chromogranin and synaptophysin. highlights sustentacular cells.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: year old female with right thoracic paraganglioma.

Specimen Taken For Protocol: 01 - Yes.

Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: right thoracic paraganglioma.

Post-Operative Diagnosis: right thoracic paraganglioma.

Operative Findings: Right paraspinal lesion.

SPECIMENS SUBMITTED: 1. ROUTINE + 5FR.SLIDES, Inferior margin r/o paraganglioma (1FS)
2. ROUTINE + 4FR.SLIDES, Inferior margin #2 r/o paraganglioma (2FS)
3. ROUTINE + 4FR.SLIDES, Lateral margin (3FS)
4. ROUTINE + 3FR.SLIDES, Medial margin (4FS)
5. SOFT TISSUE MASS, Right thoracic paraganglioma

INTRAOPERATIVE CONSULTATION:

1FS: "Inferior margin rule out paraganglioma"
1FS diagnosis: Fibroadipose tissue, negative for tumor.

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 3]
Surgical Pathology

Final Results

2FS: "Inferior margin #2 rule out paraganglioma"
2FS diagnosis: Lymph node, no tumor seen.

3FS: "Lateral margin"
3FS diagnosis: Fibroadipose tissue, no tumor seen.

4FS: "Medial margin"
4FS diagnosis: Fibroadipose tissue, no tumor seen.

The above results were communicated to the Surgical Team by

GROSS DESCRIPTION: Received fresh are 5 separate specimens labeled with the patient's name, medical record number, date of birth, and further specified as follows:

1. "Inferior margin rule out paraganglioma" consisting of a fibrous tan-red soft tissue fragment measuring 0.7 x 0.5 x 0.3 cm which is frozen in total as . Received in Surgical Pathology is a specimen matching the above description. It consists of a green cassette labeled ' ', the contents of which are entirely transferred to an orange cassette labeled .
2. "Inferior margin #2 rule out paraganglioma" consisting of a fibrous red-tan soft tissue fragment measuring 1.0 x 0.5 x 0.3 cm which is frozen in total as . Received in Surgical Pathology is a specimen matching the above description. It consists of a green cassette labeled ' ', the contents of which are entirely transferred to an orange cassette labeled .
3. "Lateral margin" consisting of a pink-tan soft tissue fragment measuring 0.8 x 0.4 x 0.3 cm which is frozen in total as 3FS. Received in Surgical Pathology is a specimen matching the above description. It consists of a green cassette labeled ' ' the contents of which are entirely transferred to an orange cassette labeled .
4. "Medial margin" consisting of a pink-tan soft tissue fragment measuring 1.5 x 0.5 x 0.1 cm which is frozen in total as 4FS. Received in Surgical Pathology is a specimen that matches the above description. It consists of a green cassette labeled ' ', the contents of which are entirely transferred to an orange cassette labeled .
5. "Right thoracic paraganglioma" consisting of an oriented tan-pink soft tissue fragment measuring 9.0 x 6.0 x 2.6 cm. In the OR, oriented the specimen and inked the deep margin black. The deep margin abuts the spine. removed a portion of the lateral margin and medial margin and submitted them for frozen section diagnosis (see specimens 3FS and 4FS). There is a central palpable nodule measuring 6.0 x 4.0 x 2.5 cm. The nodule is inked revealing a heterogeneous yellow-pink and orange cut surface.

[page 3 of 3]
Surgical Pathology

Final Results

Gross photographs are taken. Approximately 50% of tissue from the center of the nodule is procured for _____ by _____

Post procurement, the specimen is inked as follows: Superior margin in blue, inferior margin in yellow, medial margin in green, lateral margin is orange, and anterior margin is red. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The procurement was documented and performed by _____ on _____

Received in Surgical Pathology is a specimen matching the above description. A representative section of the nodule with respect to the anterior, medial, and deep margins is submitted in cassette labeled _____. A representative section of the nodule with respect to the anterior, lateral, and deep margin is submitted in cassette labeled _____. The nodule is located approximately 0.8 cm from the superior margin. The superior margin is submitted en face in cassette labeled _____.

The tumor grossly appears to abut the inferior margin. A representative section of the nodule with respect to the inferior margin is submitted in cassette labeled _____.

The medial margin is submitted en face in cassette labeled _____. Additional representative sections of the nodule are submitted in cassettes labeled _____. The remaining tissue is returned to formalin.

Gross Description dictated by _____

Accessioned: _____

Final Report Signed Out: _____

<Resident Signature> _____

<Sign Out Dr. Signature> _____

Date Report Signed: _____

Unilateral/Synchronous Primary Neoplasm		✓

hw 7/29/13

7/28/13

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By: _____

Do not file in Medical Record

Source: NCI Genomic Data Commons file 79edb0ca-e7cf-4daa-bbc1-c4b45a9e8abb (TCGA-QR-A706.AE5004D1-E443-4A82-9071-4581957761E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).